Somatic mutation profile of tumor specimen TCGA-BF-A1PU-01A (aliquot TCGA-BF-A1PU-01A-11D-A19A-08) from TCGA case TCGA-BF-A1PU, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 46.6 years (17,025 days).
Specimen TCGA-BF-A1PU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43b3c51e-1288-469c-b882-d8f2e729d600.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BF-A1PU-10A (Blood Derived Normal), aliquot TCGA-BF-A1PU-10A-01D-A19A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1c699f1-ec03-491e-98a9-60cfa48c0f86

The open-access MAF lists 96 somatic variants for this specimen: 66 protein-altering or splice-affecting, 28 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 28, Nonsense Mutation 7, Intron 2, Splice Region 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/64 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 41/55 reads (75%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- RS1 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs281865365, CM981774, COSV66107508; ClinVar: pathogenic; called by muse, varscan2
- ACSL5 | c.1750G>A p.G584R (on ENST00000354273; = p.G640R on NM_016234.3) | Missense Mutation (SNP) | VAF 40/48 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV61133595; called by muse, mutect2, varscan2
- ACTL8 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 26/33 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64862748; called by muse, mutect2, varscan2
- ADAMTS18 | c.656G>A p.G219D | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV51409142, COSV51409249; called by muse, mutect2, varscan2
- ADAMTS6 | c.99G>A p.E33= | Splice Region (SNP) | VAF 27/53 reads (51%) | catalogued as COSV66865006; called by muse, mutect2, varscan2
- ADAMTS9 | c.1859C>A p.P620Q | Missense Mutation (SNP) | VAF 72/183 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs987055817, COSV55791084; called by muse, varscan2
- AMER3 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs769333454, COSV58467112; called by mutect2, varscan2
- ANK3 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 39/49 reads (80%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.768); catalogued as COSV55082997; called by muse, mutect2, varscan2
- ARID2 | c.1468C>T p.Q490* | Nonsense Mutation (SNP) | VAF 64/77 reads (83%) | catalogued as rs865903558, COSV57596657; called by muse, mutect2, varscan2
- ATP2B2 | c.1192G>A p.V398M (on ENST00000352432; = p.V364M on NM_001683.5) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100659448, COSV100660600; called by muse, mutect2, varscan2
- BCL11A | c.1657G>A p.E553K (on ENST00000335712 / NM_001365609.1; = p.E587K on NM_018014.4) | Missense Mutation (SNP) | VAF 85/111 reads (77%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs1212578579, COSV59627157; called by muse, mutect2, varscan2
- CD163 | c.1694G>A p.G565E | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as rs1318743377, COSV63129120; called by muse, varscan2
- COL1A1 | c.2183G>A p.G728E | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56809362; called by muse, mutect2, varscan2
- COL22A1 | c.2926G>A p.G976R | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57361755; called by muse, mutect2, varscan2
- COX10 | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.18); catalogued as COSV55409108; called by muse, mutect2, varscan2
- CPAMD8 | c.1442G>A p.G481E (on ENST00000651564; = p.G434E on NM_015692.5) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV52240041, COSV99359746; called by muse, mutect2, varscan2
- CPXM2 | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 47/68 reads (69%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.554); catalogued as COSV53867139; called by muse, mutect2, varscan2
- CST4 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1452581630, COSV54150553; called by muse, varscan2
- DNAH3 | c.11594C>T p.P3865L | Missense Mutation (SNP) | VAF 100/207 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54504091; called by muse, mutect2, varscan2
- DOT1L | c.3913G>A p.G1305R | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV67113555; called by muse, mutect2, varscan2
- EFNB3 | c.902G>A p.G301E | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.839); catalogued as COSV56834953; called by muse, varscan2
- EZH1 | c.1466C>T p.P489L | Missense Mutation (SNP) | VAF 53/100 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV70549363; called by muse, mutect2, varscan2
- FBXO15 | c.1233G>A p.W411* | Nonsense Mutation (SNP) | VAF 18/37 reads (49%) | catalogued as COSV54048945; called by muse, mutect2, varscan2
- FLG | c.3799G>A p.G1267R | Missense Mutation (SNP) | VAF 74/168 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.602); catalogued as COSV64240970, COSV64249823; called by muse, mutect2, varscan2
- GCNA | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 95/234 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.326); catalogued as rs947249334, COSV65468364; called by muse, mutect2, varscan2
- GOLGB1 | c.4472C>T p.S1491F | Missense Mutation (SNP) | VAF 91/225 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61471261; called by muse, mutect2, varscan2
- GPR179 | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as rs1312249568; called by muse, mutect2, varscan2
- HTR2A | c.154C>T p.R52* | Nonsense Mutation (SNP) | VAF 42/99 reads (42%) | catalogued as COSV66326961; called by mutect2, varscan2
- IGFL1 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT tolerated (0.74); PolyPhen benign (0.042); catalogued as rs769434804, COSV71443704; called by mutect2, varscan2
- IL36RN | c.115+1G>T p.X39_splice | Splice Site (SNP) | VAF 10/36 reads (28%) | catalogued as rs1173603200, COSV61010987; called by muse, mutect2, varscan2
- IL5RA | c.150G>A p.W50* | Nonsense Mutation (SNP) | VAF 14/47 reads (30%) | catalogued as COSV56526820; called by muse, mutect2, varscan2
- KIAA0319 | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.5); catalogued as COSV65502013; called by muse, mutect2, varscan2
- LYPD6B | c.410G>A p.G137E (on ENST00000409029 / NM_001317004.1; = p.G161E on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV54520862; called by muse, mutect2, varscan2
- MARCO | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as rs770063533, COSV59052015; called by mutect2, varscan2
- MED12 | c.5237C>A p.P1746Q | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV100375383, COSV61333304; called by mutect2, varscan2
- MFSD2A | c.644G>A p.G215E (on ENST00000372809 / NM_001136493.3; = p.G202E on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65686600; called by muse, mutect2, varscan2
- MOCOS | c.1849A>G p.M617V | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746750840, COSV54342676; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NTRK1 | c.1907C>T p.A636V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as rs771421920, COSV100693092, COSV62328714; called by mutect2, varscan2
- NUP205 | c.3794A>G p.Y1265C | Missense Mutation (SNP) | VAF 65/81 reads (80%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.87); catalogued as rs1375037748, COSV53666379; called by muse, mutect2, varscan2
- OR4C3 | c.73C>T p.L25F | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV60583980, COSV60590222; called by muse, mutect2, varscan2
- OR4K5 | c.446G>T p.W149L | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60005313; called by mutect2, varscan2
- PCLO | c.5794C>T p.P1932S | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs373227645; called by muse, mutect2, varscan2
- PKHD1L1 | c.1354C>T p.H452Y | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65753714; called by mutect2, varscan2
- PLXNB3 | c.4075G>A p.E1359K | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.482); catalogued as rs1557063552, COSV62802410; called by muse, mutect2, varscan2
- RBM5 | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 53/125 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV61739118; called by muse, mutect2, varscan2
- RNF217 | c.1447C>T p.P483S (on ENST00000521654 / NM_001286398.2; = p.P191S on NM_152553.5) | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV51577740; called by muse, mutect2, varscan2
- SCN5A | c.2066G>A p.R689H | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs199473145, CM057209; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SERPINF2 | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60665833; called by muse, mutect2, varscan2
- SFPQ | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV61759315; called by mutect2, varscan2
- SLC6A11 | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 69/167 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54399260; called by muse, mutect2, varscan2
- SLIT3 | c.1405C>T p.R469* | Nonsense Mutation (SNP) | VAF 28/56 reads (50%) | catalogued as rs1394577013, COSV60602066; called by muse, mutect2, varscan2
- SNTG2 | c.764G>A p.G255E | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs748766167, COSV58007366; called by muse, mutect2, varscan2
- SPINDOC | c.787C>T p.R263* | Nonsense Mutation (SNP) | VAF 24/78 reads (31%) | catalogued as COSV99588390; called by mutect2, varscan2
- SPRR4 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV60143297; called by muse, mutect2, varscan2
- TBX4 | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV53609917; called by muse, mutect2, varscan2
- TENM1 | c.3967G>A p.D1323N | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64443876; called by muse, mutect2, varscan2
- TEX26 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs775005047, COSV66839450; called by mutect2, varscan2
- TNFRSF10B | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs199909973, COSV52394364; called by muse, mutect2, varscan2
- TSEN2 | c.912C>T p.A304= | Splice Region (SNP) | VAF 259/721 reads (36%) | catalogued as COSV53191144; called by muse, mutect2, varscan2
- TTBK1 | c.1358G>A p.R453K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV52496829; called by muse, mutect2, varscan2
- TTN | c.70300C>T p.H23434Y (on ENST00000591111; = p.H16010Y on NM_003319.4) | Missense Mutation (SNP) | VAF 47/113 reads (42%) | PolyPhen benign (0.053); catalogued as COSV60360763; called by muse, mutect2, varscan2
- TUBA3D | c.1096G>A p.G366R | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.542); catalogued as COSV58313367; called by muse, mutect2, varscan2
- VCAN | c.3205G>A p.D1069N | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.41); catalogued as rs377090663; ClinVar: uncertain significance; called by mutect2, varscan2
- WNK3 | c.4178C>T p.S1393L | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.025); catalogued as rs781830908, COSV63611806, COSV63615042; called by mutect2, varscan2
- AACS | c.1977C>T p.T659= | Silent (SNP) | VAF 20/31 reads (65%) | catalogued as COSV55540597; called by muse, varscan2
- ABCB1 | c.1392G>A p.R464= | Silent (SNP) | VAF 36/90 reads (40%) | catalogued as COSV55964054; called by muse, mutect2, varscan2
- ABCC3 | c.1320G>A p.A440= | Silent (SNP) | VAF 34/88 reads (39%) | catalogued as rs776443083, COSV53329403, COSV53329640; called by mutect2, varscan2
- ABHD1 | c.435C>T p.N145= | Silent (SNP) | VAF 26/32 reads (81%) | catalogued as COSV53208345; called by muse, mutect2, varscan2
- AGXT2 | c.496T>C p.L166= | Silent (SNP) | VAF 79/206 reads (38%) | catalogued as COSV51485520, COSV51490955; called by muse, mutect2, varscan2
- AK8 | c.831G>A p.V277= | Silent (SNP) | VAF 65/160 reads (41%) | catalogued as COSV53760788; called by muse, varscan2
- APBA2 | c.540G>A p.Q180= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs758366553, COSV68790192, COSV68795625; called by muse, mutect2, varscan2
- BRWD3 | c.1662G>A p.Q554= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as COSV64753861; called by muse, mutect2, varscan2
- C12orf54 | c.309G>A p.E103= | Silent (SNP) | VAF 102/166 reads (61%) | catalogued as rs1475036193, COSV58361120; called by muse, mutect2, varscan2
- CACNA1B | c.1563C>T p.F521= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs866097273, COSV53149811; called by muse, mutect2, varscan2
- CEACAM5 | c.1257C>T p.T419= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as rs1372155774, COSV55751846, COSV55755311; called by muse, mutect2, varscan2
- DCAF4L2 | c.852C>T p.F284= | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as COSV60477632; called by muse, mutect2, varscan2
- DDX54 | c.984C>T p.L328= | Silent (SNP) | VAF 22/26 reads (85%) | catalogued as COSV58376157; called by muse, varscan2
- FLG | c.10251G>A p.Q3417= | Silent (SNP) | VAF 84/228 reads (37%) | catalogued as rs1373277273, COSV64249813; called by muse, varscan2
- HTR1A | c.732A>T p.A244= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV60503022; called by muse, mutect2, varscan2
- L3MBTL3 | c.2289C>T p.F763= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as COSV104422336, COSV62388302; called by muse, mutect2, varscan2
- MYOM1 | c.759C>G p.S253= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV55301496; called by muse, mutect2, varscan2
- NDFIP1 | c.354C>T p.F118= | Silent (SNP) | VAF 48/120 reads (40%) | catalogued as rs556266228, COSV54076455; called by mutect2, varscan2
- OR8I2 | c.339C>T p.F113= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV56167742; called by muse, mutect2, varscan2
- PCDHB16 | c.1581C>T p.F527= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs781952097, COSV53363130, COSV53368221; called by mutect2, varscan2
- SLC24A1 | c.1116C>T p.S372= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs1391750342, COSV56054203; called by muse, varscan2
- SPACA7 | c.342C>T p.S114= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV52104111; called by muse, mutect2, varscan2
- SPINDOC | c.786C>T p.V262= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as COSV99588387; called by muse, mutect2, varscan2
- TAS2R9 | c.612C>T p.S204= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as COSV53690690; called by muse, mutect2, varscan2
- TKT | c.1668C>T p.I556= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as COSV56247191; called by muse, mutect2, varscan2
- UNC13D | c.3051G>A p.E1017= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs368211297, COSV52887752; called by muse, mutect2, varscan2
- XDH | c.2535C>T p.A845= | Silent (SNP) | VAF 58/71 reads (82%) | catalogued as COSV65151266; called by muse, varscan2
- XYLB | c.1056C>T p.S352= | Silent (SNP) | VAF 53/144 reads (37%) | catalogued as rs919718288, COSV99263866; called by muse, mutect2, varscan2
- FBXL13 | c.496-5520C>T | Intron (SNP) | VAF 39/48 reads (81%) | catalogued as rs772053164, COSV100500894; called by muse, mutect2, varscan2
- OBSCN | c.11659+3423G>A | Intron (SNP) | VAF 54/148 reads (36%) | catalogued as rs150190896, COSV99470889; called by muse, mutect2, varscan2
